Somatic mutation profile of tumor specimen TCGA-A4-8630-01A (aliquot TCGA-A4-8630-01A-11D-2396-08) from TCGA case TCGA-A4-8630, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 59.9 years (21,884 days).
Specimen TCGA-A4-8630-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0af803dc-d0b5-4120-83a9-4edbbc95a127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8630-10A (Blood Derived Normal), aliquot TCGA-A4-8630-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5268e67f-37ff-45f0-982c-f9ddf07ae910

The open-access MAF lists 59 somatic variants for this specimen: 44 protein-altering or splice-affecting, 12 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 12, Splice Site 4, Frame Shift Del 3, 3'UTR 2, In Frame Del 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AGTPBP1 | c.646A>C p.N216H | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.962); catalogued as COSV61268888; called by muse, mutect2, varscan2
- AL441992.2 | c.1193A>T p.Y398F | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV56912511; called by muse, mutect2, varscan2
- ALDH3A2 | c.1103A>G p.H368R | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51565722; called by muse, mutect2, varscan2
- ASAP3 | c.2123A>T p.E708V | Missense Mutation (SNP) | VAF 45/85 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60873215; called by muse, mutect2, varscan2
- CTSC | c.347C>G p.T116S | Missense Mutation (SNP) | VAF 107/262 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57056407; called by muse, mutect2, varscan2
- DIP2B | c.2600C>A p.P867H | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV56579414; called by muse, mutect2, varscan2
- DUOXA2 | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV50993122; called by muse, mutect2, varscan2
- ECI2 | c.894G>C p.E298D (on ENST00000380118 / NM_206836.3; = p.E268D on NM_006117.2) | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as COSV60985219; called by muse, mutect2, varscan2
- FBXO11 | c.1623T>G p.N541K (on ENST00000403359 / NM_001190274.2; = p.N457K on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.246); catalogued as COSV104413094, COSV57016659; called by muse, mutect2, varscan2
- FRG1 | c.260-2A>G p.X87_splice | Splice Site (SNP) | VAF 5/16 reads (31%) | catalogued as COSV56996607; called by muse, mutect2, varscan2
- ITGB5 | c.2017G>A p.V673M | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs375122712; called by muse, mutect2, varscan2
- JMY | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); catalogued as rs1427987682, COSV68659484; called by muse, mutect2, varscan2
- MUC16 | c.31226C>G p.T10409R | Missense Mutation (SNP) | VAF 84/221 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.076); catalogued as COSV67447699; called by muse, mutect2, varscan2
- MYO9A | c.5696A>G p.E1899G | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV61847992; called by muse, mutect2, varscan2
- NFKB2 | c.1051G>A p.G351R | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as rs45580031, COSV50042041, COSV99192673; called by muse, mutect2, varscan2
- OR6C1 | c.53A>G p.D18G | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.371); catalogued as COSV65572705; called by muse, varscan2
- PRAG1 | c.3569G>A p.G1190D | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.281); catalogued as rs1274821532, COSV58157789; called by muse, mutect2
- PRRC2C | c.160C>G p.R54G (on ENST00000367742; = p.R52G on NM_015172.4) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100145063, COSV58901668; called by muse, mutect2, varscan2
- RAI1 | c.5455G>A p.A1819T | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55389643; called by muse, mutect2, varscan2
- RALGAPA1 | c.4207C>G p.P1403A | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV51877353; called by muse, mutect2, varscan2
- S100A3 | c.293C>G p.P98R | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.161); catalogued as rs199928185, COSV62876534; called by muse, mutect2, varscan2
- SBF1 | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as rs1241940829, COSV62365980; called by muse, mutect2, varscan2
- SCNN1B | c.1189C>T p.R397C | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as rs372303239; called by muse, mutect2, varscan2
- SLAIN2 | c.1127T>A p.V376E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.026); catalogued as COSV51904377; called by muse, mutect2, varscan2
- SLC8A1 | c.1852A>G p.K618E | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV60470860; called by muse, mutect2, varscan2
- SMCHD1 | c.2299C>T p.Q767* | Nonsense Mutation (SNP) | VAF 18/44 reads (41%) | catalogued as rs1258926987, COSV55252310; called by muse, mutect2, varscan2
- TDRD3 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52153460, COSV52164135; called by muse, mutect2, varscan2
- TEKT1 | c.1050-1G>T p.X350_splice | Splice Site (SNP) | VAF 28/97 reads (29%) | catalogued as COSV100106405; called by muse, mutect2, varscan2
- TMEM204 | c.559A>T p.I187F | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV54151709; called by muse, mutect2, varscan2
- TMEM52 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.017); catalogued as COSV57068793; called by muse, mutect2, varscan2
- TRIM11 | c.812C>A p.T271N | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.248); catalogued as COSV52856416, COSV52856484; called by muse, mutect2, varscan2
- TTF2 | c.1341C>G p.I447M | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV65632102; called by muse, mutect2, varscan2
- VGLL4 | c.854C>T p.S285F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV56074770, COSV99810540; called by muse, mutect2, varscan2
- ZNF346 | c.517+1G>C p.X173_splice | Splice Site (SNP) | VAF 26/76 reads (34%) | catalogued as COSV56155546; called by muse, mutect2, varscan2
- ZNF585A | c.2149C>A p.P717T (on ENST00000292841 / NM_001288800.2; = p.P662T on NM_152655.3) | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53061904; called by mutect2, varscan2
- ZNF585A | c.2148G>T p.K716N (on ENST00000292841 / NM_001288800.2; = p.K661N on NM_152655.3) | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV53061918; called by muse, mutect2, varscan2
- ZNF93 | c.1007C>T p.T336I | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV59374196; called by muse, mutect2, varscan2
- ADAM7 | c.782_783dup p.S262Ifs*4 | Frame Shift Ins (INS) | VAF 20/96 reads (21%) | called by mutect2, pindel, varscan2
- AMPH | c.1653del p.H551Qfs*9 | Frame Shift Del (DEL) | VAF 45/97 reads (46%) | called by mutect2, pindel, varscan2
- ASNS | c.1290del p.L430Ffs*7 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | called by mutect2, pindel, varscan2
- SMG5 | c.2819del p.A940Efs*10 | Frame Shift Del (DEL) | VAF 61/203 reads (30%) | called by mutect2, pindel, varscan2
- SUPT16H | c.2997_2998+1del p.X999_splice | Splice Site (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- TAF15 | c.1451G>A p.G484D (on ENST00000605844 / NM_139215.3; = p.G481D on NM_003487.4) | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- TTN | c.76102_76104del p.I25368del (on ENST00000591111; = p.I17944del on NM_003319.4) | In Frame Del (DEL) | VAF 53/125 reads (42%) | called by mutect2, pindel, varscan2
- CELA3B | c.423C>T p.L141= | Silent (SNP) | VAF 34/109 reads (31%) | catalogued as rs1009106982, COSV61403080; called by muse, mutect2, varscan2
- CHSY3 | c.777C>T p.R259= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as COSV59272136; called by muse, mutect2, varscan2
- CSMD2 | c.10407A>T p.T3469= | Silent (SNP) | VAF 86/224 reads (38%) | catalogued as COSV53883901; called by muse, mutect2, varscan2
- DEF8 | c.453G>A p.E151= (on ENST00000268676 / NM_207514.3; = p.E90= on NM_017702.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV51918029; called by muse, mutect2
- ELMO3 | c.1650T>A p.T550= (on ENST00000652269; = p.T497= on NM_024712.5) | Silent (SNP) | VAF 41/64 reads (64%) | catalogued as COSV58526549; called by muse, mutect2, varscan2
- HELZ | c.5766C>T p.L1922= | Silent (SNP) | VAF 34/116 reads (29%) | catalogued as COSV62376529; called by muse, mutect2, varscan2
- LETMD1 | c.816G>A p.L272= | Silent (SNP) | VAF 67/156 reads (43%) | catalogued as COSV50396709; called by muse, mutect2, varscan2
- RAD50 | c.3222A>G p.A1074= | Silent (SNP) | VAF 101/222 reads (45%) | catalogued as rs1486641970, COSV54748190; ClinVar: likely benign; called by muse, mutect2, varscan2
- RRNAD1 | c.1314T>C p.H438= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as COSV63928698, COSV63929381; called by muse, mutect2, varscan2
- SSU72 | c.282G>A p.R94= | Silent (SNP) | VAF 67/184 reads (36%) | catalogued as rs138912153, COSV52215477; called by muse, mutect2, varscan2
- TBCK | c.2628C>T p.G876= (on ENST00000273980 / NM_001163436.4; = p.G813= on NM_033115.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV56752349; called by muse, mutect2, varscan2
- TCF4 | c.1266T>C p.I422= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV61891188; called by muse, mutect2, varscan2
- FGFR3 | c.*902A>G | 3'UTR (SNP) | VAF 11/26 reads (42%) | catalogued as COSV53392965; called by muse, mutect2, varscan2
- HLA-DRB9 | n.176G>A | RNA (SNP) | VAF 36/122 reads (30%) | called by muse, mutect2
- PLK1 | c.*146del | 3'UTR (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
